Somatic mutation profile of tumor specimen 0DS0ZY from CCDI case PBCHIB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 16.7 years (6,102 days).
Specimen 0DS0ZY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a603f39b-31c8-4b7e-b0e5-263c938f5067.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0ZD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/702a1cae-8185-4c9e-bf74-803e3c89aa97

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, 3'UTR 2, Silent 2, Intron 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSBG1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 25/512 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.142); catalogued as rs1303683057, COSV99356913; called by muse, mutect2
- CTNNA2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 213/848 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.136); catalogued as rs765394694, COSV100561245, COSV58152576; called by muse, varscan2
- DUOXA2 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 259/1041 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as rs1276058897; called by muse, mutect2, varscan2
- GFER | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 339/795 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1028553365; called by muse, mutect2, varscan2
- OR8K1 | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 188/850 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.013); catalogued as COSV54404674; called by muse, mutect2, varscan2
- RIF1 | c.7270C>G p.L2424V | Missense Mutation (SNP) | VAF 405/956 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775132686; called by muse, mutect2, varscan2
- ANKRD36C | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 49/1281 reads (4%) | called by muse, mutect2
- CBR4 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 233/614 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CSMD3 | c.5800A>G p.T1934A (on ENST00000297405 / NM_001363185.1; = p.T1830A on NM_052900.3) | Missense Mutation (SNP) | VAF 50/750 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- EDN1 | c.113A>C p.K38T | Missense Mutation (SNP) | VAF 58/1051 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.038); called by muse, mutect2
- FRMD4B | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 48/1294 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2
- LAX1 | c.1083_1084del p.H361Qfs*7 | Frame Shift Del (DEL) | VAF 226/664 reads (34%) | called by mutect2, varscan2
- NAGS | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 211/582 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLD1 | c.2807C>A p.T936N | Missense Mutation (SNP) | VAF 42/850 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); called by muse, mutect2
- SAMD9L | c.3571A>G p.M1191V | Missense Mutation (SNP) | VAF 199/824 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLK | c.1352A>C p.K451T | Missense Mutation (SNP) | VAF 32/1234 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.058); called by muse, mutect2
- TTC16 | c.1262A>C p.Q421P | Missense Mutation (SNP) | VAF 229/316 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- VCAM1 | c.1734A>C p.L578F | Missense Mutation (SNP) | VAF 89/1537 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- SERTAD2 | c.717A>G p.T239= | Silent (SNP) | VAF 244/672 reads (36%) | called by muse, varscan2
- ZNF813 | c.498G>A p.K166= | Silent (SNP) | VAF 271/1099 reads (25%) | called by muse, mutect2, varscan2
- ADGRB2 | c.*41C>A | 3'UTR (SNP) | VAF 88/202 reads (44%) | catalogued as rs779497391, COSV57079380, COSV99926935; called by muse, varscan2
- MOV10L1 | c.2628-18A>C | Intron (SNP) | VAF 98/246 reads (40%) | called by muse, mutect2, varscan2
- TMEM196 | c.*126A>T | 3'UTR (SNP) | VAF 97/219 reads (44%) | called by muse, mutect2, varscan2
- ZNF433 | c.4-30G>A | Intron (SNP) | VAF 130/318 reads (41%) | called by muse, varscan2
